Somatic mutation profile of tumor specimen MMRF_1512_1_BM_CD138pos (aliquot MMRF_1512_1_BM_CD138pos_T1_KBS5U_L04303) from MMRF case MMRF_1512, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: female; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 61.8 years (22,572 days).
Specimen MMRF_1512_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 77c38ecc-dfa8-4b7e-8732-3cdbd100f341.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_1512_1_PB_Whole (Blood Derived Normal), aliquot MMRF_1512_1_PB_Whole_C3_KBS5U_L04314; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2a084e3f-b120-4e21-b233-f280aaea6a30

The open-access MAF lists 113 somatic variants for this specimen: 41 protein-altering or splice-affecting, 23 silent, 49 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 35, 3'UTR 24, Silent 23, Intron 17, 5'UTR 4, Splice Site 3, 5'Flank 2, 3'Flank 2, Nonsense Mutation 2, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.350A>G p.K117R | Missense Mutation (SNP) | VAF 12/44 reads (27%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV55937655; called by muse, mutect2, varscan2
- KRAS | c.34G>A p.G12S | Missense Mutation (SNP) | VAF 32/251 reads (13%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen possibly damaging (0.582); catalogued as rs121913530, CM076251, COSV55497461, COSV55497469, COSV55497582, COSV56157736; ClinVar: not provided / pathogenic; called by muse, mutect2, varscan2
- A1CF | c.461C>T p.S154L | Missense Mutation (SNP) | VAF 78/130 reads (60%) | SIFT tolerated (0.1); PolyPhen benign (0.017); catalogued as rs377106588, COSV51023004; called by muse, mutect2, varscan2
- ANKRD13A | c.501G>A p.M167I | Missense Mutation (SNP) | VAF 61/61 reads (100%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.977); catalogued as rs764720723; called by muse, mutect2, varscan2
- ARHGAP12 | c.2123A>G p.N708S | Missense Mutation (SNP) | VAF 39/103 reads (38%) | SIFT deleterious (0.03); PolyPhen benign (0.307); catalogued as rs140324216; called by muse, mutect2, varscan2
- CCDC183 | c.1201G>A p.E401K | Missense Mutation (SNP) | VAF 166/251 reads (66%) | SIFT tolerated (0.74); PolyPhen benign (0); catalogued as rs532281379; called by muse, mutect2, varscan2
- CELF5 | c.643G>A p.D215N | Missense Mutation (SNP) | VAF 62/210 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.254); catalogued as COSV53014410; called by muse, mutect2, varscan2
- COL24A1 | c.1708-2A>G p.X570_splice | Splice Site (SNP) | VAF 42/108 reads (39%) | catalogued as rs1365803484; called by muse, varscan2
- COL6A1 | c.2468C>T p.T823M | Missense Mutation (SNP) | VAF 33/34 reads (97%) | SIFT deleterious (0.05); PolyPhen benign (0.015); catalogued as rs749442445, COSV62613673; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- EGR1 | c.191G>A p.S64N | Missense Mutation (SNP) | VAF 68/109 reads (62%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0); catalogued as rs200514514; called by muse, mutect2, varscan2
- IGHD3-16 | c.5T>A p.L2* | Nonsense Mutation (SNP) | VAF 18/18 reads (100%) | catalogued as rs782301945; called by muse, mutect2, varscan2
- IGKV2-24 | c.50-1G>A p.X17_splice | Splice Site (SNP) | VAF 71/74 reads (96%) | catalogued as rs769792187; called by muse, varscan2
- IGLV3-1 | c.118A>C p.T40P | Missense Mutation (SNP) | VAF 32/86 reads (37%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.705); catalogued as rs189772470; called by muse, varscan2
- IGLV3-1 | c.164A>G p.Q55R | Missense Mutation (SNP) | VAF 28/86 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.905); catalogued as rs543933563; called by muse, varscan2
- IGLV3-1 | c.338C>T p.T113I | Missense Mutation (SNP) | VAF 40/86 reads (47%) | SIFT deleterious (0.01); PolyPhen benign (0.092); catalogued as rs759680385; called by muse, mutect2
- IGLV4-60 | c.273C>G p.S91R | Missense Mutation (SNP) | VAF 71/169 reads (42%) | SIFT tolerated (0.08); PolyPhen benign (0.05); catalogued as rs374752274, COSV66503537; called by muse, mutect2, varscan2
- KCNV2 | c.1208C>T p.T403M | Missense Mutation (SNP) | VAF 42/124 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs745375996; called by muse, mutect2, varscan2
- LIFR | c.532C>T p.R178C | Missense Mutation (SNP) | VAF 48/139 reads (35%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.866); catalogued as rs757892555, COSV54689883; called by muse, mutect2, varscan2
- MYO18A | c.1480A>G p.I494V | Missense Mutation (SNP) | VAF 17/43 reads (40%) | SIFT tolerated (0.36); PolyPhen benign (0.007); catalogued as rs184921820; called by muse, mutect2, varscan2
- PAX5 | c.46G>A p.G16R | Missense Mutation (SNP) | VAF 29/41 reads (71%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as COSV63911668, COSV63914348; called by muse, mutect2, varscan2
- PCDH8 | c.2254G>A p.V752I | Missense Mutation (SNP) | VAF 45/97 reads (46%) | SIFT tolerated (0.84); PolyPhen benign (0.081); catalogued as rs1448663370; called by muse, mutect2, varscan2
- PLAAT1 | c.686C>T p.T229I (on ENST00000650797; = p.T124I on NM_020386.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 109/166 reads (66%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs373503937; called by muse, mutect2, varscan2
- RGS11 | c.1291G>A p.V431M (on ENST00000397770 / NM_183337.3; = p.V410M on NM_003834.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 22/51 reads (43%) | SIFT deleterious (0.04); PolyPhen benign (0.066); catalogued as rs374550808; called by muse, mutect2, varscan2
- RUNX1T1 | c.1192G>A p.D398N (on ENST00000265814 / NM_001198628.1; = p.D371N on NM_004349.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 31/57 reads (54%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.698); catalogued as COSV99753183; called by muse, mutect2, varscan2
- SULT4A1 | c.661G>A p.A221T | Missense Mutation (SNP) | VAF 40/76 reads (53%) | SIFT tolerated (0.11); PolyPhen benign (0.007); catalogued as rs1464303215; called by muse, mutect2, varscan2
- TAS1R2 | c.1927A>G p.I643V | Missense Mutation (SNP) | VAF 69/123 reads (56%) | SIFT tolerated (1); PolyPhen benign (0.021); catalogued as rs1481735919; called by muse, mutect2, varscan2
- COL21A1 | c.1596+2T>G p.X532_splice | Splice Site (SNP) | VAF 23/60 reads (38%) | called by muse, mutect2, varscan2
- FUT9 | c.928A>C p.K310Q | Missense Mutation (SNP) | VAF 50/81 reads (62%) | SIFT tolerated (0.19); PolyPhen benign (0.044); called by muse, mutect2, varscan2
- GJA1 | c.130G>T p.A44S | Missense Mutation (SNP) | VAF 9/73 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.939); called by muse, mutect2, varscan2
- IKBKG | c.38G>C p.R13T | Missense Mutation (SNP) | VAF 57/65 reads (88%) | PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- ITSN1 | c.5089A>G p.K1697E | Missense Mutation (SNP) | VAF 27/70 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- LAIR2 | c.291del p.L98Ffs*23 | Frame Shift Del (DEL) | VAF 15/54 reads (28%) | called by mutect2, pindel, varscan2
- LRP5 | c.2095A>C p.I699L | Missense Mutation (SNP) | VAF 39/94 reads (41%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.871); called by muse, mutect2, varscan2
- LSP1 | c.469G>T p.A157S | Missense Mutation (SNP) | VAF 12/24 reads (50%) | SIFT tolerated (0.76); PolyPhen benign (0.001); called by mutect2, varscan2
- MAGI1 | c.4210G>A p.A1404T | Missense Mutation (SNP) | VAF 113/189 reads (60%) | SIFT tolerated, low confidence (0.55); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- MTCL1 | c.4883G>T p.C1628F (on ENST00000306329 / NM_001378206.1; = p.C1309F on NM_015210.4) | Missense Mutation (SNP) | VAF 8/82 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- MUC16 | c.34754G>A p.S11585N | Missense Mutation (SNP) | VAF 61/93 reads (66%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0); called by muse, mutect2, varscan2
- RAP1GAP2 | c.919C>T p.R307* | Nonsense Mutation (SNP) | VAF 30/68 reads (44%) | called by muse, mutect2, varscan2
- SLAMF8 | c.81C>A p.S27R | Missense Mutation (SNP) | VAF 79/165 reads (48%) | SIFT deleterious (0); PolyPhen benign (0.266); called by muse, mutect2, varscan2
- SPRY2 | c.87C>A p.D29E | Missense Mutation (SNP) | VAF 57/131 reads (44%) | SIFT tolerated (0.54); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ZNF227 | c.1790T>C p.V597A | Missense Mutation (SNP) | VAF 43/139 reads (31%) | SIFT tolerated (0.07); PolyPhen benign (0.257); called by muse, mutect2, varscan2
- ALDH1L1 | c.1536T>C p.G512= | Silent (SNP) | VAF 62/94 reads (66%) | called by muse, mutect2, varscan2
- AMOTL2 | c.1335C>T p.R445= | Silent (SNP) | VAF 17/63 reads (27%) | catalogued as rs755522162; called by muse, mutect2, varscan2
- CDH10 | c.2007C>T p.A669= | Silent (SNP) | VAF 89/125 reads (71%) | catalogued as rs1353472387, COSV52589315; called by muse, mutect2, varscan2
- DHRS2 | c.816G>A p.A272= | Silent (SNP) | VAF 62/136 reads (46%) | catalogued as rs757863804, COSV51634310; called by muse, mutect2, varscan2
- GFPT1 | c.1746T>C p.Y582= (on ENST00000357308 / NM_001244710.2; = p.Y564= on NM_002056.4) | Silent (SNP) | VAF 30/83 reads (36%) | catalogued as rs777579226; called by muse, mutect2, varscan2
- IGLV3-1 | c.336C>T p.S112= | Silent (SNP) | VAF 40/87 reads (46%) | catalogued as rs73880716; called by muse, mutect2
- IGLV4-60 | c.153C>T p.S51= | Silent (SNP) | VAF 66/138 reads (48%) | catalogued as rs191540570; called by muse, mutect2, varscan2
- KDM4A | c.1338A>G p.Q446= | Silent (SNP) | VAF 6/88 reads (7%) | called by muse, mutect2
- OR2G6 | c.462C>T p.I154= | Silent (SNP) | VAF 8/70 reads (11%) | called by muse, mutect2, varscan2
- PPP1R13L | c.1044C>T p.P348= | Silent (SNP) | VAF 10/32 reads (31%) | catalogued as rs770587293; called by muse, varscan2
- PSD3 | c.315C>T p.D105= | Silent (SNP) | VAF 65/128 reads (51%) | catalogued as rs1351592551; called by muse, mutect2, varscan2
- PTPRD | c.3258A>G p.T1086= | Silent (SNP) | VAF 18/242 reads (7%) | called by muse, mutect2
- RASAL3 | c.273G>T p.G91= | Silent (SNP) | VAF 7/32 reads (22%) | catalogued as rs781299406; called by muse, mutect2, varscan2
- RPTOR | c.3210C>T p.V1070= | Silent (SNP) | VAF 14/36 reads (39%) | called by muse, mutect2
- SLC16A7 | c.987C>A p.L329= | Silent (SNP) | VAF 14/106 reads (13%) | catalogued as COSV53899340; called by muse, mutect2, varscan2
- STARD9 | c.6366T>C p.D2122= | Silent (SNP) | VAF 27/106 reads (25%) | called by muse, mutect2, varscan2
- TEAD1 | c.462G>T p.P154= | Silent (SNP) | VAF 10/18 reads (56%) | catalogued as rs752862372, COSV57567740; called by muse, mutect2
- TECTA | c.4467G>A p.A1489= | Silent (SNP) | VAF 25/60 reads (42%) | catalogued as rs1555127484, COSV50691170; called by muse, mutect2, varscan2
- TPI1 | c.57G>C p.G19= | Silent (SNP) | VAF 10/68 reads (15%) | called by muse, mutect2
- TTN | c.45735A>T p.G15245= (on ENST00000591111; = p.G7821= on NM_003319.4) | Silent (SNP) | VAF 58/227 reads (26%) | called by muse, mutect2, varscan2
- UBXN7 | c.1035C>G p.A345= | Silent (SNP) | VAF 62/234 reads (26%) | called by muse, mutect2, varscan2
- UNC13C | c.1212C>T p.I404= | Silent (SNP) | VAF 81/240 reads (34%) | catalogued as rs1379778602; called by muse, mutect2, varscan2
- WDR97 | c.1833T>C p.I611= | Silent (SNP) | VAF 56/144 reads (39%) | called by muse, mutect2, varscan2
- ABHD4 | c.*209C>T | 3'UTR (SNP) | VAF 3/42 reads (7%) | called by muse, mutect2
- ADD2 | c.-22G>A | 5'UTR (SNP) | VAF 83/156 reads (53%) | catalogued as rs781795877, COSV52465733, COSV52474923; called by muse, mutect2, varscan2
- AKAP9 | c.10968+88G>A | Intron (SNP) | VAF 6/15 reads (40%) | called by muse, mutect2, varscan2
- ANO5 | c.-143A>C | 5'UTR (SNP) | VAF 35/77 reads (45%) | called by muse, mutect2
- APOA4 | c.*88A>G | 3'UTR (SNP) | VAF 19/44 reads (43%) | called by muse, mutect2, varscan2
- ARHGEF4 | c.-366G>A | 5'UTR (SNP) | VAF 82/173 reads (47%) | catalogued as rs943638580; called by muse, mutect2, varscan2
- B3GALT5 | c.*792T>G | 3'UTR (SNP) | VAF 53/92 reads (58%) | called by muse, mutect2, varscan2
- BDH2 | c.419-329T>A | Intron (SNP) | VAF 7/46 reads (15%) | called by muse, mutect2, varscan2
- CALM2 | c.4-1611T>A | Intron (SNP) | VAF 31/65 reads (48%) | called by muse, mutect2, varscan2
- CCN2 | c.*564A>C | 3'UTR (SNP) | VAF 9/16 reads (56%) | called by muse, mutect2, varscan2
- CHRM3 | c.*5677G>A | 3'UTR (SNP) | VAF 56/110 reads (51%) | called by muse, mutect2, varscan2
- CTBP1 | chr4:1249813 G>C | 5'Flank (SNP) | VAF 33/73 reads (45%) | called by muse, mutect2, varscan2
- DAOA | c.*111+317C>T | Intron (SNP) | VAF 30/176 reads (17%) | catalogued as rs900232746; called by muse, mutect2, varscan2
- DDR2 | c.1728+29C>G | Intron (SNP) | VAF 17/195 reads (9%) | called by muse, mutect2
- DEFB134 | chr8:11993544 C>T | 3'Flank (SNP) | VAF 23/42 reads (55%) | called by muse, mutect2, varscan2
- EPHA7 | c.*650A>T | 3'UTR (SNP) | VAF 53/104 reads (51%) | called by muse, mutect2, varscan2
- ERGIC3 | c.*53C>T | 3'UTR (SNP) | VAF 6/84 reads (7%) | called by muse, mutect2
- FER | c.*6261T>C | 3'UTR (SNP) | VAF 21/61 reads (34%) | called by muse, mutect2, varscan2
- FOXL2NB | c.221-154C>T | Intron (SNP) | VAF 31/86 reads (36%) | catalogued as rs753722830; called by muse, mutect2, varscan2
- GATAD2B | c.*858A>T | 3'UTR (SNP) | VAF 24/60 reads (40%) | called by muse, mutect2, varscan2
- GRIA2 | c.2292-230C>T | Intron (SNP) | VAF 19/55 reads (35%) | called by muse, mutect2, varscan2
- IFI44L | c.528-17C>G | Intron (SNP) | VAF 36/96 reads (38%) | called by muse, mutect2, varscan2
- LDLRAD2 | c.*1338C>T | 3'UTR (SNP) | VAF 43/85 reads (51%) | catalogued as rs924145474; called by muse, mutect2, varscan2
- LYSMD1 | c.*769C>T | 3'UTR (SNP) | VAF 21/40 reads (53%) | called by muse, mutect2, varscan2
- MARS1 | c.109+52C>T | Intron (SNP) | VAF 17/18 reads (94%) | catalogued as rs1169323318; called by muse, mutect2, varscan2
- MIB1 | c.*4400G>C | 3'UTR (SNP) | VAF 55/115 reads (48%) | called by muse, mutect2, varscan2
- MMP2 | c.154-1178G>A | Intron (SNP) | VAF 7/50 reads (14%) | called by muse, mutect2, varscan2
- NAA30 | c.*3201G>A | 3'UTR (SNP) | VAF 35/69 reads (51%) | called by muse, mutect2, varscan2
- NBAS | c.*54G>A | 3'UTR (SNP) | VAF 33/53 reads (62%) | called by muse, mutect2, varscan2
- NHLRC2 | c.*3666C>T | 3'UTR (SNP) | VAF 20/51 reads (39%) | called by muse, mutect2, varscan2
- NR2C2AP | c.-197del | 5'UTR (DEL) | VAF 73/218 reads (33%) | called by mutect2, pindel, varscan2
- NR3C2 | c.*1443T>A | 3'UTR (SNP) | VAF 18/119 reads (15%) | called by muse, mutect2, varscan2
- OR8S1 | chr12:48528187 G>A | 3'Flank (SNP) | VAF 63/142 reads (44%) | called by muse, mutect2, varscan2
- PDE10A | c.*965A>C | 3'UTR (SNP) | VAF 4/84 reads (5%) | called by muse, mutect2
- QPCT | c.547-27_547-25del | Intron (DEL) | VAF 20/50 reads (40%) | called by mutect2, pindel, varscan2
- RCAN1 | c.*600G>A | 3'UTR (SNP) | VAF 67/69 reads (97%) | catalogued as rs554708492; called by muse, mutect2, varscan2
- RETSAT | c.*137A>C | 3'UTR (SNP) | VAF 87/616 reads (14%) | called by muse, mutect2, varscan2
- SATL1 | chrX:85109041 G>A | 5'Flank (SNP) | VAF 64/67 reads (96%) | called by muse, mutect2, varscan2
- SEL1L | c.*2837T>C | 3'UTR (SNP) | VAF 53/91 reads (58%) | called by muse, mutect2, varscan2
- SHROOM4 | c.*997+1256T>G | Intron (SNP) | VAF 24/29 reads (83%) | called by muse, mutect2, varscan2
- SPA17 | c.-28+100G>A | Intron (SNP) | VAF 83/157 reads (53%) | called by muse, mutect2, varscan2
- SPATA18 | c.1479+83T>C | Intron (SNP) | VAF 34/65 reads (52%) | called by muse, mutect2, varscan2
- SSTR1 | c.*906C>A | 3'UTR (SNP) | VAF 22/51 reads (43%) | catalogued as rs1375421802; called by muse, mutect2, varscan2
- TAFA5 | c.112+54847C>T | Intron (SNP) | VAF 14/29 reads (48%) | catalogued as rs1268703712; called by muse, mutect2, varscan2
- TMED5 | c.*4460A>G | 3'UTR (SNP) | VAF 102/219 reads (47%) | called by muse, mutect2, varscan2
- TMEM241 | c.*1761dup | 3'UTR (INS) | VAF 118/288 reads (41%) | catalogued as rs1486156454; called by mutect2, varscan2
- TSPAN12 | c.360+1484C>T | Intron (SNP) | VAF 76/160 reads (48%) | catalogued as rs551881362; called by muse, varscan2
- WBP2 | c.*173G>T | 3'UTR (SNP) | VAF 15/26 reads (58%) | catalogued as COSV52882733; called by muse, mutect2, varscan2
- ZNF726 | c.226+361G>T | Intron (SNP) | VAF 22/60 reads (37%) | called by mutect2, varscan2
